Somatic mutation profile of tumor specimen TCGA-ED-A66X-01A (aliquot TCGA-ED-A66X-01A-11D-A30V-10) from TCGA case TCGA-ED-A66X, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 35.4 years (12,947 days).
Specimen TCGA-ED-A66X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8d90ab6-1c1b-4732-9097-46e36754ff05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A66X-10A (Blood Derived Normal), aliquot TCGA-ED-A66X-10A-01D-A30V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ed0d1d6-0b24-4569-af8b-9ffaa644e991

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 31, Silent 11, Nonsense Mutation 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKH | c.771T>G p.I257M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52480904; called by muse, mutect2, varscan2
- CAMTA2 | c.1949A>G p.K650R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.108); catalogued as COSV61834934; called by muse, varscan2
- CHTOP | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.602); catalogued as rs138105302; called by muse, mutect2
- CILP | c.457A>G p.S153G | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV56024244; called by muse, mutect2, varscan2
- DPY19L2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs760662810, COSV60543394, COSV60544422; called by muse, mutect2, varscan2
- EEA1 | c.4100T>C p.V1367A | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs757264285, COSV59285795; called by muse, mutect2, varscan2
- EIF3E | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV55202981, COSV55204341, COSV99623360; called by muse, mutect2
- EPHB1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV67653976, COSV67661612, COSV67662917; called by muse, mutect2, varscan2
- FASN | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs771740708, COSV60754763; called by muse, mutect2
- GABRA4 | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51927594; called by muse, mutect2, varscan2
- KRT19 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV64238452; called by muse, mutect2
- LRRTM3 | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63665467, COSV63666233; called by muse, mutect2
- MKI67 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201650569, COSV64074330; called by muse, mutect2, varscan2
- MUC4 | c.14752T>A p.S4918T (on ENST00000463781 / NM_018406.7; = p.S682T on NM_004532.6) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.045); catalogued as COSV57780155; called by muse, varscan2
- NFKBIL1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs755428062, COSV58214407; called by muse, mutect2, varscan2
- OR10A6 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | catalogued as rs147185885; called by muse, mutect2, varscan2
- OR2T6 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs766459334, COSV63216271; called by muse, mutect2, varscan2
- OR51I1 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs762410237, COSV66507897; called by muse, mutect2, varscan2
- PFAS | c.3346G>A p.G1116S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774571165, COSV58980323; called by muse, mutect2, varscan2
- PLEKHM2 | c.2839C>T p.P947S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs1436914399, COSV53817037; called by muse, mutect2, varscan2
- PLXDC2 | c.625A>C p.S209R | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV65903925; called by muse, mutect2, varscan2
- PYHIN1 | c.412A>C p.K138Q | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63722433; called by muse, mutect2
- RYR1 | c.7640C>T p.A2547V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs751482960, COSV62089660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN10A | c.1775A>G p.K592R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1559442319, COSV71861341; called by mutect2, varscan2
- SCUBE3 | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); catalogued as COSV51456883, COSV51461288; called by muse, mutect2, varscan2
- SLC15A2 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV55197841; called by muse, mutect2, varscan2
- SLCO2B1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56935206; called by muse, mutect2
- TENM2 | c.7360C>T p.P2454S (on ENST00000518659 / NM_001122679.2; = p.P2215S on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69130392; called by mutect2, varscan2
- TJP1 | c.3896A>G p.K1299R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV62041963, COSV62045982; called by muse, varscan2
- TJP1 | c.3895A>T p.K1299* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | catalogued as COSV100632139; called by muse, varscan2
- TMEM200A | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422589435, COSV51649187; called by muse, mutect2
- TTBK2 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as rs960191942, COSV51161283; called by mutect2, varscan2
- XRN1 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.339); catalogued as rs141258147; called by muse, mutect2, varscan2
- ACADL | c.796dup p.I266Nfs*6 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- MAOB | c.-10_6delinsT | Translation Start Site (DEL) | VAF 15/43 reads (35%) | called by pindel, varscan2*
- BAZ1B | c.2184C>T p.F728= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV59991153; called by muse, mutect2, varscan2
- ISM1 | c.1050C>T p.D350= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs572363345, COSV52603697; called by muse, mutect2, varscan2
- KIF26B | c.831G>A p.A277= | Silent (SNP) | VAF 22/256 reads (9%) | catalogued as rs537827807, COSV68572393; called by muse, mutect2
- RCC2 | c.387C>T p.Y129= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as rs1291395571, COSV64905840; called by muse, varscan2
- SIGLEC8 | c.291A>G p.Q97= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as rs944855147, COSV58473744; called by muse, mutect2, varscan2
- TADA2A | c.559T>C p.L187= | Silent (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- TRIM67 | c.2271C>G p.L757= | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as COSV64158858; called by muse, mutect2, varscan2
- TRPM3 | c.450C>T p.G150= (on ENST00000357533 / NM_001366142.2; = p.G119= on NM_001007471.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/175 reads (14%) | catalogued as rs145250735, COSV62470197; called by muse, mutect2, varscan2
- TUBB4A | c.1083G>A p.L361= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV51152330; called by muse, mutect2, varscan2
- VPS13B | c.6165G>T p.L2055= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV62141920; called by muse, mutect2
- YY1 | c.264G>T p.P88= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV51762435; called by muse, mutect2, varscan2
